CCDI case PBCAHA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3af32171-729a-4cdd-b850-f6cfb7e12dc2

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 2.8 years (1,013 days).

Biospecimens (3 samples)
- Sample 0DM8U9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM8UF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DM8W1: Tissue type: Tumor; Specimen type: Solid Tissue.
